Somatic mutation profile of cancer-model specimen HCM-CSHL-0814-C54-85A (3D Organoid, passage 8; aliquot HCM-CSHL-0814-C54-85A-01D-A85L-36), derived from the primary tumor of HCMI case HCM-CSHL-0814-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen HCM-CSHL-0814-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3df2b65f-7096-4102-a153-30253c694a8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0814-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0814-C54-11A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db5caeec-4f54-4cd6-8f45-aadb7bb80a19

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, In Frame Del 2, Intron 2, Splice Region 1, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 260/261 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs767975152, COSV52198901; called by muse, varscan2
- ARHGEF2 | c.2671G>A p.D891N (on ENST00000361247 / NM_001162383.2; = p.D863N on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 292/596 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.886); catalogued as rs767282425, COSV100559885; called by muse, mutect2, varscan2
- CDH23 | c.8239G>A p.V2747M | Missense Mutation (SNP) | VAF 248/564 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370616165; called by muse, mutect2, varscan2
- CDH4 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 143/718 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs895024295, COSV100848575, COSV64661310; called by muse, mutect2, varscan2
- CEACAM5 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1568709454; called by muse, varscan2
- CEP131 | c.2636C>T p.A879V (on ENST00000269392 / NM_001319228.2; = p.A876V on NM_014984.4) | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs564816685, COSV53951076; called by muse, varscan2
- CIITA | c.2819C>A p.T940K | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.305); catalogued as COSV60861224; called by muse, mutect2, varscan2
- CPEB2 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 108/513 reads (21%) | SIFT deleterious, low confidence (0); catalogued as rs867024774; called by muse, mutect2, varscan2
- DMD | c.9091G>A p.V3031I | Missense Mutation (SNP) | VAF 121/426 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs143426249, COSV58903820; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- DNAH8 | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 132/314 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs562900966, COSV59443185; called by muse, varscan2
- DRC7 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 104/526 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.481); catalogued as rs1242355910; called by muse, mutect2, varscan2
- EIF2AK2 | c.594C>T p.L198= | Splice Region (SNP) | VAF 65/321 reads (20%) | catalogued as rs149581029; called by muse, mutect2, varscan2
- GPRC6A | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs773802327; called by muse, varscan2
- OLFM3 | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1388947737; called by muse, mutect2
- PMAIP1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 134/260 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV54054291; called by muse, varscan2
- PNLDC1 | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV99277779; called by muse, mutect2, varscan2
- PRSS38 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 36/916 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.231); catalogued as rs750191354; called by muse, mutect2
- QRICH2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 118/225 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs536269106, COSV53154644; called by muse, mutect2, varscan2
- SNRNP70 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 143/517 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1297433105; called by muse, mutect2, varscan2
- ANKRD26 | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ANKRD50 | c.4098T>G p.N1366K | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.187); called by muse, mutect2
- ARHGAP35 | c.2647_2648dup p.Q884Ffs*4 | Frame Shift Ins (INS) | VAF 222/365 reads (61%) | called by mutect2, varscan2
- COQ8B | c.1457A>G p.Y486C | Missense Mutation (SNP) | VAF 146/443 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMPPB | c.131_139del p.A44_V46del | In Frame Del (DEL) | VAF 83/542 reads (15%) | called by mutect2, pindel, varscan2
- KIAA0232 | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 265/399 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- KIAA1109 | c.6763G>A p.G2255S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRBA2 | c.996C>G p.N332K | Missense Mutation (SNP) | VAF 356/356 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MBD5 | c.945T>A p.C315* | Nonsense Mutation (SNP) | VAF 118/344 reads (34%) | called by muse, mutect2, varscan2
- PNISR | c.59T>C p.M20T | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PRPF8 | c.2765_2770del p.L922_D923del | In Frame Del (DEL) | VAF 126/490 reads (26%) | called by mutect2, pindel, varscan2
- RNF150 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- SACS | c.4778A>C p.K1593T | Missense Mutation (SNP) | VAF 153/309 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SETD1B | c.5830A>G p.K1944E | Missense Mutation (SNP) | VAF 130/340 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, varscan2
- HFM1 | c.1524G>A p.K508= | Silent (SNP) | VAF 197/321 reads (61%) | catalogued as COSV104398726; called by muse, mutect2, varscan2
- IGLC3 | c.201G>A p.A67= | Silent (SNP) | VAF 166/1375 reads (12%) | catalogued as rs372319362; called by muse, varscan2
- ITGB5 | c.2394G>A p.V798= | Silent (SNP) | VAF 65/340 reads (19%) | catalogued as rs150701217; called by muse, mutect2, varscan2
- KANSL1L | c.2601T>G p.L867= | Silent (SNP) | VAF 61/266 reads (23%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.93C>T p.P31= | Silent (SNP) | VAF 60/221 reads (27%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1761G>A p.P587= | Silent (SNP) | VAF 107/388 reads (28%) | catalogued as rs782747674, COSV62024146; called by muse, mutect2, varscan2
- SPANXN2 | c.369G>A p.Q123= | Silent (SNP) | VAF 110/595 reads (18%) | called by muse, mutect2, varscan2
- SPTBN2 | c.3687C>T p.H1229= | Silent (SNP) | VAF 115/383 reads (30%) | catalogued as rs1032153896; called by muse, mutect2, varscan2
- ZNF768 | c.660A>T p.T220= | Silent (SNP) | VAF 128/861 reads (15%) | called by mutect2, varscan2
- CUL7 | c.-123C>T | 5'UTR (SNP) | VAF 20/688 reads (3%) | called by muse, mutect2
- KCNQ1 | c.1393+28739del | Intron (DEL) | VAF 165/230 reads (72%) | called by mutect2, pindel, varscan2
- UNC13B | c.761+5535G>C | Intron (SNP) | VAF 24/198 reads (12%) | called by muse, mutect2, varscan2
